Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A1YD, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A1YD-01A (Primary Tumor).

[page 1 of 3]
DEPARTMENT OF PATHOLOGY

ICD-0-3

Carcinoma, papillary, follicular variant
8340/3

Site: Thyroid, NOS C73.9

3/6/11 *lw*

Surgical Pathology Consultation Report

Patient

Name:

MRN:

DOB:

Service:

Visit #:

Accession #:

Collected:

Received:

Gender: F

Location:

Reported:

HCN:

Facility:

Ordering

MD:

Copy To:

Specimen(s) Received

1. Lymph node: Query right paratracheal QS
2. Lymph node: Right paratracheal lymph nodes
3. Parathyroid: Adenoma
4. Thyroid: Right thyroid lobe and isthmus, stitch right superior pole

Diagnosis

1, 2. No pathological diagnosis: Lymph nodes, 4 (right paratracheal) biopsies

3. Enlarged cellular gland consistent with diffuse hyperplasia: Parathyroid (site not specified) parathyroidectomy specimen

4. Multifocal papillary carcinoma, 3.7 cm right, and 0.3 cm isthmus; underlying nodular hyperplasia: Thyroid

No pathological diagnosis: Lymph node
- (right) hemithyroidectomy specimen
Synoptic Data

Specimen Type:	Right Hemi-Thyroidectomy
Tumour Focality:	Multifocal
-----Dominant Tumour-----	
Histologic Type:	Papillary carcinoma, follicular variant
Tumour Site:	Right Lobe
Tumour Size:	Greatest Dimension: 3.7 cm
	Additional Dimensions: 2.8 x 1.8 cm
Capsular Invasion:	Encapsulated
	Locally invasive
Extrathyroidal Extension:	Absent
Margins:	Margins uninvolved by carcinoma

[page 2 of 3]
Venous/Lymphatic (Large/Small Vessel) Invasion (V/L): Absent

-----Secondary Tumour-----

Histologic Type: Papillary carcinoma, follicular variant

Tumour Site: Isthmus

Tumour Size: Greatest Dimension: 0.3 cm

Capsular Invasion: Unencapsulated

Extrathyroidal Extension: Absent

Margins: Margins uninvolved by carcinoma

Venous/Lymphatic (Large/Small Vessel) Invasion (V/L): Absent

Pathologic Staging (pTNM): pT2: Tumor more than 2 cm, but not more than 4 cm,
limited to thyroid

pN0: No regional lymph node metastasis

Number of regional lymph nodes examined: 5

Number of regional lymph nodes involved: 0

pMX: Distant metastasis cannot be assessed

Additional Pathologic Findings: Nodular hyperplasia

verified by:

Electronically

MD

Gross Description

1. The specimen labeled with the patient's name and as "lymph node: Query right paratracheal qs" consists of a piece of tissue that measures 0.5 x 0.4 x 0.3 cm. It is frozen for intraoperative consultation.

1A frozen section block resubmitted

2. The specimen labeled with the patient's name and as "lymph node: Right paratracheal lymph nodes" consists of four pieces of tissue that measure from 0.2 x 0.2 x 0.1 cm to 0.5 x 0.4 x 0.2 cm.

2A submitted in toto

3. The specimen labeled with the patient's name and as "parathyroid: Adenoma" consists of one piece of red-tan nodular tissue that measures 1.8 x 0.8 x 0.5 cm.

3A bisected and submitted in toto

4. The specimen labeled with the patient's name and as "right thyroid lobe and isthmus, stitch right superior pole" consists of a right hemithyroidectomy specimen that is oriented with a suture and weighs 15.6 g. The lobe measures 4.5 cm SI x 3.0 cm ML x 2.0 cm AP and the isthmus measures 2.0 SI x 0.7 cm ML x 0.7 cm AP. The external surfaces have fibrous adhesions. No parathyroid glands or lymph nodes are identified grossly. The external surface is painted with silver nitrate. The lobe contains a well delineated solid nodule that measures 3.7 x 2.8 x 1.8 cm. The isthmus contains two well delineated solid nodules that measure 0.2 x 0.2 x 0.2 cm and 0.3 x 0.3 x 0.3 cm. The remainder of the thyroid tissue is grossly unremarkable. Sections of the right lobe nodule and normal tissue are stored frozen. The remainder of the specimen is submitted as follows:

4A-4I lobe, superior to inferior

4J, 4K isthmus

Quick Section Diagnosis

1A - Benign lymph node. Reported

[page 3 of 3]
MD

Microscopic Description

IMMUNOHISTOCHEMISTRY: AE1/AE3 immunostaining in specimen 2 (right paratracheal lymph nodes) is negative.

Source: NCI Genomic Data Commons file fcc4c1c1-abdf-421b-90dd-a90019274695 (TCGA-EM-A1YD.20E7B915-FBA5-422C-98CD-008444AAF8F0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).